Somatic mutation profile of tumor specimen TCGA-28-2514-01A (aliquot TCGA-28-2514-01A-02W-0837-08) from TCGA case TCGA-28-2514, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.8 years (16,737 days).
Specimen TCGA-28-2514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20faedeb-edd0-427c-8f6c-95b2c66d2818.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2514-10A (Blood Derived Normal), aliquot TCGA-28-2514-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2ba3a0e-2743-4e83-be36-2350e30e62ff

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Frame Shift Ins 4, Splice Site 3, Nonsense Mutation 2, In Frame Ins 1, Intron 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 21/120 reads (18%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCB11 | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265851804, COSV55602632; called by muse, mutect2, varscan2
- AFM | c.1603A>C p.M535L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56922562; called by muse, mutect2, varscan2
- ANKS3 | c.868+1G>A p.X290_splice | Splice Site (SNP) | VAF 18/143 reads (13%) | catalogued as rs1267163643, COSV58512244; called by muse, mutect2, varscan2
- ARFGEF3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 128/331 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1326151522, COSV52472440; called by muse, mutect2, varscan2
- CAMK4 | c.851A>C p.D284A | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56685004; called by muse, mutect2, varscan2
- CNGB1 | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs868226949, COSV51906019; called by muse, mutect2, varscan2
- CREBBP | c.5986G>A p.A1996T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1302332843, COSV52143090; called by muse, mutect2
- DLK1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754418195, COSV57990874; called by muse, mutect2, varscan2
- DPP10 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1055873408, COSV59686211; called by muse, mutect2, varscan2
- EIF4H | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56083743; called by muse, mutect2, varscan2
- ETNPPL | c.1303+2T>C p.X435_splice | Splice Site (SNP) | VAF 42/86 reads (49%) | catalogued as COSV56597865, COSV99625260; called by muse, mutect2, varscan2
- FAM83E | c.889dup p.Q297Pfs*33 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | catalogued as rs773971919; called by mutect2, varscan2
- FBLN2 | c.2686G>A p.G896S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.164); catalogued as rs1055157175, COSV55488310; called by muse, mutect2, varscan2
- GRM8 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760631675, COSV58874971; called by muse, mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 46/389 reads (12%) | catalogued as rs746492036; called by mutect2, varscan2
- IL26 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 230/630 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs749146583, COSV57490251; called by muse, mutect2, varscan2
- IMPACT | c.932T>A p.V311E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.034); catalogued as COSV99408844; called by muse, mutect2
- KIR2DS4 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 658/2455 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.067); catalogued as rs760743437; called by muse, mutect2, varscan2
- KRT39 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762707953, COSV62918131; called by muse, mutect2
- LCOR | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as rs1316089530; called by muse, mutect2, varscan2
- LRRC66 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 293/601 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1426002150, COSV58637149; called by muse, mutect2, varscan2
- MAMSTR | c.485dup p.H163Tfs*9 (on ENST00000318083 / NM_001130915.2; = p.H60Tfs*9 on NM_182574.2) | Frame Shift Ins (INS) | VAF 29/132 reads (22%) | catalogued as rs752869239; called by mutect2, varscan2
- MIPEP | c.603G>A p.K201= | Splice Region (SNP) | VAF 89/230 reads (39%) | catalogued as rs1192020026, COSV66302104; called by muse, mutect2, varscan2
- ONECUT2 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs1312900705, COSV72203894; called by muse, mutect2, varscan2
- PDZD3 | c.550A>T p.S184C (on ENST00000531114; = p.S118C on NM_024791.4) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV52710345; called by muse, mutect2, varscan2
- PILRA | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52202741; called by muse, mutect2, varscan2
- PRIM1 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57718297; called by muse, mutect2, varscan2
- PRR27 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs577881430, COSV60641128; called by muse, mutect2, varscan2
- RAD21 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52064665; called by muse, mutect2, varscan2
- RBM47 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778126567, COSV55942848; called by muse, mutect2, varscan2
- SERPINA7 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 141/158 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59665958, COSV59666149; called by muse, mutect2, varscan2
- SIN3A | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196648474, COSV64581745, COSV64584116; called by muse, mutect2, varscan2
- STAU1 | c.724G>A p.A242T (on ENST00000371856 / NM_001319135.1; = p.A161T on NM_004602.3) | Missense Mutation (SNP) | VAF 126/500 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61460360; called by mutect2, varscan2
- SULT1B1 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs374341407; called by muse, mutect2, varscan2
- SYNPO2 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV61118658; called by muse, mutect2, varscan2
- SYTL2 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 237/584 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100314200, COSV60364503; called by muse, mutect2, varscan2
- TNFSF14 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 338/1180 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs772753769, COSV55590283; called by muse, mutect2, varscan2
- TRAT1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 101/283 reads (36%) | catalogued as rs148894492; called by muse, mutect2, varscan2
- ZNF337 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 34/621 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV53320931; called by muse, mutect2
- ZNF98 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV100757423; called by muse, mutect2, varscan2
- ADAM29 | c.2077_2079dup p.C693dup | In Frame Ins (INS) | VAF 20/48 reads (42%) | called by mutect2, pindel, varscan2
- ARHGEF7 | c.917+3_917+6del p.X306_splice (on ENST00000375741 / NM_001113511.2; = p.X128_splice on NM_003899.5 and 5 other RefSeq transcripts) | Splice Site (DEL) | VAF 20/72 reads (28%) | called by pindel, varscan2
- BTRC | c.1230G>A p.M410I (on ENST00000370187 / NM_033637.4; = p.M374I on NM_003939.5) | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2
- MKI67 | c.8157_8165del p.S2719_K2721del | In Frame Del (DEL) | VAF 311/364 reads (85%) | called by mutect2, pindel, varscan2
- TMEM94 | c.2604_2605del p.K868Nfs*18 | Frame Shift Del (DEL) | VAF 182/342 reads (53%) | called by mutect2, pindel
- ABCA13 | c.11988C>T p.T3996= | Silent (SNP) | VAF 38/238 reads (16%) | catalogued as rs199785430; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4029C>T p.L1343= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV63247681; called by muse, mutect2, varscan2
- CELF5 | c.1359C>T p.S453= | Silent (SNP) | VAF 117/371 reads (32%) | catalogued as rs372894450; called by muse, mutect2, varscan2
- IFT80 | c.450G>A p.V150= | Silent (SNP) | VAF 218/509 reads (43%) | catalogued as COSV58453118; called by muse, varscan2
- IGF2BP1 | c.1596C>T p.N532= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as rs151135710; called by muse, mutect2
- LDLR | c.981C>T p.H327= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs1060499933, COSV52946340; called by muse, mutect2, varscan2
- NLRP2 | c.2016C>T p.D672= | Silent (SNP) | VAF 98/254 reads (39%) | catalogued as rs374613201; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.340C>T p.L114= (on ENST00000374531 / NM_001037293.2; = p.L112= on NM_007203.5) | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as rs1261312617, COSV57133902; called by muse, mutect2, varscan2
- PCDHB7 | c.873G>T p.T291= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as rs782276991, COSV50825293; called by muse, varscan2
- PTPRH | c.3180G>A p.P1060= | Silent (SNP) | VAF 156/576 reads (27%) | catalogued as rs769586690, COSV54750776; called by muse, mutect2, varscan2
- SLC9A4 | c.570C>T p.D190= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as rs755300636, COSV54835828; called by muse, mutect2, varscan2
- TNFSF14 | c.387C>T p.H129= | Silent (SNP) | VAF 61/183 reads (33%) | catalogued as rs147375196; called by muse, mutect2, varscan2
- ZFPL1 | c.435C>T p.P145= | Silent (SNP) | VAF 31/317 reads (10%) | catalogued as rs766209202, COSV99297685; called by muse, mutect2, varscan2
- PTPRN2 | c.2783+2202G>A | Intron (SNP) | VAF 64/211 reads (30%) | catalogued as COSV101153307; called by muse, mutect2, varscan2
